Gene-level copy-number profile of tumor specimen TCGA-VT-A80G-01A from TCGA case TCGA-VT-A80G, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Undifferentiated sarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of pelvis; Age at diagnosis: 66.1 years (24,128 days).
Specimen TCGA-VT-A80G-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.ec841cbe-4820-4d18-87e7-e64416d0d3fb.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VT-A80G-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 817 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/108528ee-0b3f-4c39-914a-25852dd64462

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 212; copy number 1: 5,312; copy number 2: 20,992; copy number 3: 20,712; copy number 4: 10,572; copy number 5: 1,108; copy number 6: 604; copy number 7: 206; copy number 8: 88.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VT-A80G-01A-11D-A36I-01): tumor purity 0.86, ploidy 2.79, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 212 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:150,584–2,512,580, 50 genes: AC131281.2, WBP1LP3, OR4F21, SEPTIN14P8, AC131281.1, RPL23AP53, ZNF596, AC004908.2, AC004908.1, AC004908.3, AC136777.2, AC136777.1, FAM87A, FBXO25, AC083964.1, AC083964.2, TDRP, ERICH1, AC100797.1, DLGAP2, AC100797.4, AC026950.2, AC129915.3, AC110288.1, AF067845.2, AF067845.1, AF067845.5, AF067845.4, DLGAP2-AS1, AC100810.6, AC100810.2, CLN8, AC100810.3, AC100810.1, AC019257.8, MIR3674, AC100810.7, MIR596, ARHGEF10, AC019257.9, AC019257.1, KBTBD11-OT1, KBTBD11, AC019257.2, AC245164.1, MYOM2, MIR7160, AC245164.2, AC245519.1, AC245519.2.
- chr8:2,518,998–2,522,182, 1 gene: AC245187.1.
- chr9:12,685,439–13,034,326, 8 genes: TYRP1, LURAP1L-AS1, RN7SL849P, LURAP1L, Y_RNA, AL161449.2, PRDX1P1, AL161449.1.
- chr9:15,776,181–15,776,286, 1 gene: RNU6-14P.
- chr9:19,507,452–20,332,277, 8 genes (within-gene range 0–6): SLC24A2, C11orf98P1, AL158077.2, AL158077.1, AL591222.1, AL591222.2, AL591222.3, AL512635.1.
- chr9:20,411,148–20,418,427, 2 genes: MIR4473, RNU4-26P.
- chr9:21,135,598–30,690,272, 116 genes (within-gene range 0–5) (broad region; genes not listed).
- chr10:44,712–942,743, 16 genes: AL713922.1, TUBB8, IL9RP2, ZMYND11, AL713922.2, RNA5SP297, DIP2C, RNA5SP298, RN7SL754P, AL669841.1, AL358216.1, MIR5699, PRR26, AL157709.1, LARP4B, AL359878.2.
- chr14:51,436,038–51,599,952, 2 genes (within-gene range 0–2): SETP2, FRMD6-AS2.
- chr14:51,522,864–51,522,967, 1 gene: RNU6-1291P.
- chr14:78,059,942–78,060,278, 1 gene: FXNP1.
- chr14:78,177,803–78,231,619, 2 genes: RNA5SP388, RPS26P48.
- chr16:5,010,909–5,043,999, 2 genes (within-gene range 0–1): NAGPA-AS1, NAGPA.
- chr16:5,044,122–5,066,110, 1 gene (within-gene range 0–2): C16orf89.
- chr21:19,620,695–19,621,545, 1 gene: NIPA2P3.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 294 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:190,624,890–192,185,815, 11 genes, copy number 7: LINC01720, AL139135.1, AL139135.2, AL138927.1, HNRNPA1P46, AL713866.1, AL713866.2, LINC01680, LINC02770, AL359081.1, RGS18.
- chr1:192,246,708–192,367,285, 3 genes, copy number 7: AL513175.1, AL513175.2, RGS21.
- chr3:33,388,336–35,872,198, 21 genes, copy number 7 (within-gene range 3–7): UBP1, RNU7-110P, RNA5SP128, CLASP2, COX6CP10, AC112220.1, SDAD1P3, AC112220.2, PDCD6IP, LINC01811, AC123023.2, AC123023.1, AC018359.1, AC007483.1, FECHP1, KRT8P18, RNU6-243P, ARPP21, ARPP21-AS1, MIR128-2, AC104308.1.
- chr3:94,935,760–94,938,024, 2 genes, copy number 8: AC140059.1, WDR82P1.
- chr4:22,594,196–23,285,573, 6 genes, copy number 7: AC098583.1, AC098583.2, GBA3, CDC42P6, AC097512.1, AC092440.1.
- chr4:24,768,049–25,418,498, 12 genes, copy number 7 (within-gene range 3–7): AC006390.1, HNRNPA1P65, SOD3, CCDC149, LGI2, SEPSECS, SEPSECS-AS1, PI4K2B, AC104662.1, U2, ZCCHC4, ANAPC4.
- chr4:171,812,254–178,287,285, 73 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr4:178,685,886–182,917,936, 28 genes, copy number 7 (within-gene range 4–7): AC017087.1, AC018710.1, AC020551.1, AC021193.1, AC108169.1, AC096747.1, NDUFB5P1, AC104803.1, LINC00290, AC019235.1, LINC02500, AC093840.1, AC093840.2, AC084741.1, TEMN3-AS1, RN7SKP13, TENM3-AS1, CCNHP1, TENM3, AC108142.1, MIR1305, RNU2-34P, RN7SKP67, AC079226.2, AC079226.1, AC114798.1, AC079766.1, DCTD.
- chr9:3,824,127–4,348,392, 1 gene, copy number 8 (within-gene range 4–8): GLIS3.
- chr9:4,070,906–7,961,224, 85 genes, copy number 8 (broad region; genes not listed).
- chr16:35,363,412–35,912,516, 52 genes, copy number 7 (within-gene range 6–7): LINC01566, FRG2GP, AGGF1P4, FRG2IP, RARRES2P7, AGGF1P5, C2orf69P3, AC018558.4, ZNF971P, AC018558.6, FRG2DP, RARRES2P10, AGGF1P6, AC018558.2, C2orf69P2, AC018558.3, AC018558.7, AC018558.1, TP53TG3HP, AC018558.5, RARRES2P8, AGGF1P7, C2orf69P1, C1QL1P1, KIF18BP1, AC092325.1, AC106785.1, RNA5SP406, RNA5SP407, RNA5SP408, RNA5SP409, LINC02167, RNA5SP410, RNA5SP411, RNA5SP412, RNA5SP413, RNA5SP414, RNA5SP415, RNA5SP416, RNA5SP417, RNA5SP418, RNA5SP419, RNA5SP420, RNA5SP421, RNA5SP422, RNA5SP423, AC106785.2, HMGN2P41, VN1R70P, AC116553.1, AC116553.2, PPP1R1AP2.

Autosomal genes at a single copy (total copy number 1): 3,810. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
